Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012425-09A.1 (aliquot TARGET-15-SJMPAL012425-09A.1-01D) from TARGET case TARGET-15-SJMPAL012425, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,103 days).
Specimen TARGET-15-SJMPAL012425-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a2dcef4-7a94-49a8-8825-5e97c7b08280.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012425-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012425-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ad62c45-c470-42ae-8249-26e0bc9e3db3

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Splice Site 2, Splice Region 1, 3'Flank 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DES | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs62636492, CM070890; ClinVar: likely pathogenic / not provided / uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV99220958; called by muse, mutect2, varscan2
- GDF5 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1046039478, COSV100976703; called by muse, mutect2
- LIMCH1 | c.342C>A p.V114= | Splice Region (SNP) | VAF 5/44 reads (11%) | catalogued as COSV58277518; called by muse, mutect2
- MYADML2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs760112339; called by muse, mutect2, varscan2
- RTN1 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.487); catalogued as rs770804495; called by muse, mutect2, varscan2
- SYNPO2 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61115786; called by muse, mutect2, varscan2
- CYLC2 | c.591C>G p.N197K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDEM3 | c.2390-1G>T p.X797_splice | Splice Site (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- GANC | c.2064C>A p.H688Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen possibly damaging (0.616); called by mutect2, varscan2
- KIAA1549 | c.3887G>T p.S1296I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MYH1 | c.2435+1G>T p.X812_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- NCAPH | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- THAP10 | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA7A | c.828G>T p.L276= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- NCOR1 | c.4514-18T>A | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088398 C>A | 3'Flank (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
